Surgical pathology report (de-identified scan), TCGA case TCGA-AA-3696, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AA-3696-01A (Primary Tumor).

Diagnosis:

Partial (sigmoid) colon resection material with an ulcerated carcinoma of the colon characterized histologically as a moderately differentiated colorectal adenocarcinoma, showing circular growth in the intestinal wall over a length of 3.5 cm and extending to within 6 cm of a resection margin.

Invasive tumor spread within all parietal layers as far as the adjoining mesocolic fatty tissue.

Colon otherwise shows several pseudodiverticula and slight chronically scarring peridiverticulitis

Oral and aboral resection margins tumor-free.

One of 26 lymph nodes with a metastasis of the colon carcinoma not extending over the capsule.

Other lymph nodes with uncharacteristic reactive lesions.

Tumor stage thus pT3 pN1 (1/26) L0 V0; G2 R0

Source: NCI Genomic Data Commons file 35ae4688-8240-4cdc-8bcf-1ca1d75e1212 (TCGA-AA-3696.5356D8AB-D569-41AF-BD68-4378154D3AE7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).